CGCI case BLGSP-71-30-00651 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b90bb23f-143c-47aa-95db-4d7569fd5a64

Demographics
Sex at birth: female; Age at index: 61 years; Vital status: Dead; Days to death: 228 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Overlapping lesion of female genital organs; Classification of tumor: primary; Age at diagnosis: 61.0 years (22,297 days); Year of diagnosis: 2010; Method of diagnosis: Other; Ann Arbor pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 214 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Mediastinal lymph nodes; Sites of involvement: Ovary, NOS / Uterus / Mediastinal soft tissue / Omentum.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Mediastinal; Tumor largest dimension diameter: 3.8 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: 11 days; Days to treatment end: 116 days; Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 11 days; Days to treatment end: 116 days; Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Etoposide + Methotrexate; Initial disease status: Recurrent Disease; Days to treatment start: 149 days; Days to treatment end: 210 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 133 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 133 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 214 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (FISH): Normal.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- Epstein-Barr Virus (ISH): Negative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00651-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: FFPE; Days to sample procurement: 0 days; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00651-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00651-01-BCL6: Tissue microarray coordinates: K3,L3.
  Slide BLGSP-71-30-00651-01-BCL2: Tissue microarray coordinates: K3,L3.
  Slide BLGSP-71-30-00651-01-Ki67: Tissue microarray coordinates: K3,L3.
  Slide BLGSP-71-30-00651-01-CD3: Tissue microarray coordinates: K3,L3.
  Slide BLGSP-71-30-00651-01-CD10: Tissue microarray coordinates: K3,L3.
  Slide BLGSP-71-30-00651-01-EBER: Tissue microarray coordinates: K3,L3.
  Slide BLGSP-71-30-00651-01-CD20: Tissue microarray coordinates: K3,L3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 4; Extranodal involvment other: omentum; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: vaginal wall curettings; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: para-aortic.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: BCL2.
- Tests performed: Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event diagnosis evidence: Convincing Imaging; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2: Therapy regimen: Recurrence; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: intrethecal methotrexate and cytarabine, etoposide; Treatment best response: Clinical Progressive Disease.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00651-01A-01E-0001-01:
- % tumour: 90
